Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BK, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BK-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED]

Specimens Submitted:

- 1: SP: Left thigh tru cut biopsy (fs)
- 2: SP: Sarcoma left anterior thigh

DIAGNOSIS:

1. SOFT TISSUE, LEFT THIGH, TRU-CUT BIOPSY:
- HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA (SEE PART 2).
2. SOFT TISSUE, LEFT ANTERIOR THIGH, RESECTION:
- HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA, WITH PLEOMORPHIC AND FOCALLY MYXOID FEATURES.
- TUMOR INVOLVES SKELETAL MUSCLE AND FIBROADIPOSE TISSUE.
- TUMOR SHOWS AREAS OF NECROSIS, ESTIMATED GROSSLY AS 20-30%.
- TUMOR SIZE: 12.9 x 8.6 x 9.3 CM.
- SURGICAL MARGINS ARE FREE, BUT TUMOR IS 0.15 CM FROM THE DEEP RESECTION MARGIN.
- IMMUNOHISTOCHEMICAL STAINS WERE PERFORMED AND TUMOR IS NEGATIVE FOR S100, HMB45, AE1:AE3, 34BE12, AND DESMIN, SUPPORTING THE DIAGNOSIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received fresh for frozen section consultation, labeled "left thigh tru-cut biopsy" and consists of one fragment of needle core tissue measuring 2.5 x 0.1 x 0.1 cm. Half of the tissue submitted for frozen section. The remaining tissue is entirely submitted for permanent.

** Continued on next page **

CLUE ICD-O-3
Sarcoma, pleomorphic
undifferentiated (8802/3)
(8805/3)
Code to highest 8805/3
path
Sarcoma, pleomorphic
8802/3
Site ① Thigh NOS
C49.2
JA 11/22/13

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 3

Summary of sections:
FSC -- frozen section control
RT - remaining tissue

2) The specimen is received fresh labeled "sarcoma left anterior thigh" and consists of a single unoriented segment of muscle and adipose tissue measuring 17.5 x 10.2 x 9.2 cm. The muscle and fascia is inked overlying the mass. The specimen is sectioned to reveal a mass that measures 12.9 x 8.6 x 9.3 cm and is colored yellow/tan with areas that are more fleshy in appearance as well as other areas of necrosis, fibrosis, and hemorrhage. There are a couple of cystic areas within the mass the largest of which measures 3.1 x 1.5 x 0.9 cm and they are filled with dark brown fluid. Approximately 20-30% of the tumor appears necrotic. The mass is surrounded by a fascia and muscle and in multiple areas and is 0.1 cm from the inked margin. The unoriented distal and proximal margins are 2.0 and 2.2 cm from the mass. Tissue is submitted for TPS and photos are taken. Representative sections submitted.

RM- radial/deep margin
T-tumor
UM-unoriented distal/proximal margins

Summary of Sections:
Part 1: SP: Left thigh tru cut biopsy (fs)

Block	Sect.	Site	PCs
1		fsc	1
1		RT	1

Part 2: SP: Sarcoma left anterior thigh

Block	Sect.	Site	PCs
2		RM	2
9		T	9
1		UM	1

Intraoperative Consultation:
Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: SP: Left thigh tru cut biopsy
(fs): HIGH GRADE PLEOMORPHIC TUMOR, COMPATIBLE WITH SARCOMA

PERMANENT DIAGNOSIS: SAME

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

Page 3 of 3

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: Left thigh tru cut biopsy
(fs): HIGH GRADE PLEOMORPHIC TUMOR, COMPATIBLE WITH SARCOMA

PERMANENT DIAGNOSIS: SAME

** End of Report **

Source: NCI Genomic Data Commons file 37a857b2-a1a1-4016-a009-b9349b8feb53 (TCGA-DX-A8BK.0D240C8E-A1BD-4B06-8BA6-77A32EB8A356.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).